Somatic mutation profile of tumor specimen TCGA-D3-A3C8-06A (aliquot TCGA-D3-A3C8-06A-12D-A19A-08) from TCGA case TCGA-D3-A3C8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 58.3 years (21,281 days).
Specimen TCGA-D3-A3C8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a8767ea-a9e3-409f-8d98-ce2c76d1ba2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3C8-10A (Blood Derived Normal), aliquot TCGA-D3-A3C8-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59a0f2fa-2d63-45a9-9eec-8d1f5dcf0214

The open-access MAF lists 457 somatic variants for this specimen: 306 protein-altering or splice-affecting, 144 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 277, Silent 144, Nonsense Mutation 24, RNA 3, Splice Site 2, Frame Shift Ins 2, Intron 2, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by mutect2, varscan2
- A2M | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV59384618; called by mutect2, varscan2
- ABCB4 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV55933743; called by mutect2, varscan2
- AC006059.2 | c.1579C>G p.R527G | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as COSV59606306, COSV59607104; called by muse, mutect2
- ADH1C | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV72463418; called by muse, mutect2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by mutect2, varscan2
- ALDOC | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52024003; called by muse, mutect2
- ALOX15B | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66479244; called by mutect2, varscan2
- AMPD2 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1184762721, COSV99857424; called by muse, mutect2, varscan2
- ANK3 | c.9253G>A p.G3085R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV55050634; called by muse, mutect2
- ANK3 | c.7967G>A p.G2656E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs371772122; called by mutect2, varscan2
- ANKRD44 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV56552086; called by mutect2, varscan2
- APC | c.3566C>T p.S1189L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV57334822, COSV57368194; called by mutect2, varscan2
- ARID1B | c.6607C>T p.L2203F | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51656652; called by muse, varscan2
- ARMT1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV66178456; called by muse, mutect2
- ARSF | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63839279; called by muse, mutect2, varscan2
- ASNSD1 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53623283; called by muse, mutect2
- ATP6V1C2 | c.500A>T p.D167V | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55359067; called by muse, mutect2
- ATXN7L2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60204233; called by muse, mutect2
- BTBD7 | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as rs537138286, COSV58284609; called by muse, mutect2
- C2orf80 | c.207G>A p.L69= | Splice Region (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100378373, COSV58015784; called by muse, mutect2, varscan2
- C6orf118 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs199710080, COSV57812764; called by mutect2, varscan2
- CACNA1C | c.3056T>C p.V1019A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59707328; called by muse, mutect2, varscan2
- CACNA2D1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV62374760, COSV62376147; called by mutect2, varscan2
- CADPS | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs906307436, COSV51873515; called by mutect2, varscan2
- CARD6 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV54565204; called by muse, mutect2, varscan2
- CASZ1 | c.2614C>T p.L872F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1457137360, COSV59734043; called by muse, mutect2, varscan2
- CBLB | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV51423991; called by muse, mutect2
- CCDC60 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV59542144; called by muse, mutect2
- CCNB3 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.559); catalogued as COSV52071737; called by muse, mutect2, varscan2
- CDH17 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1330730887, COSV50326841; called by muse, mutect2, varscan2
- CDH18 | c.342A>T p.K114N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56912248; called by mutect2, varscan2
- CDHR2 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV56136628; called by muse, mutect2, varscan2
- CEP164 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs865780691, COSV54042770, COSV54044847; called by muse, mutect2, varscan2
- CEP350 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238293711, COSV62600401; called by muse, mutect2
- CFAP45 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1038417813, COSV63648600; called by muse, mutect2, varscan2
- CFAP54 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV61571481; called by muse, mutect2, varscan2
- CFH | c.2103G>A p.W701* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as CM1510266, COSV66407241; called by muse, mutect2, varscan2
- CLIP4 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60748513; called by muse, mutect2
- COL17A1 | c.1717+1G>A p.X573_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as COSV62226110; called by muse, mutect2, varscan2
- COL4A4 | c.1670G>C p.G557A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61630869; called by muse, mutect2
- COL6A6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as rs889564954, COSV62017697; called by muse, mutect2
- COL6A6 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62021579; called by muse, mutect2, varscan2
- COL8A1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV53732092; called by mutect2, varscan2
- COPS2 | c.795T>G p.Y265* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV54644747; called by muse, mutect2
- CRAMP1 | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51963362; called by mutect2, varscan2
- CSF2RB | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV53256600; called by muse, mutect2, varscan2
- CSMD2 | c.7207C>T p.L2403F | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV53897542; called by muse, mutect2
- CYP2E1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53312608; called by muse, mutect2
- DCAF1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1050905217, COSV60041844; called by muse, mutect2
- DEFB115 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV68723046; called by mutect2, varscan2
- DGKB | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs772215117, COSV51772068; called by mutect2, varscan2
- DHX57 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs762534427, COSV54883718; called by mutect2, varscan2
- DMD | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.135); catalogued as COSV55862262; called by muse, mutect2, varscan2
- DNAH5 | c.8674G>A p.E2892K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV54214871; called by mutect2, varscan2
- DNAH6 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV52854807; called by muse, mutect2, varscan2
- DNAH7 | c.4702G>A p.D1568N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as COSV56758034; called by mutect2, varscan2
- DNAH8 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV59435239; called by mutect2, varscan2
- DNTT | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV64522821; called by mutect2, varscan2
- DOCK11 | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52236157; called by mutect2, varscan2
- DPP3 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs867142856, COSV64756359; called by muse, mutect2, varscan2
- DPY19L2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV60541094; called by muse, mutect2, varscan2
- DPYD | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64594169, COSV64603653; called by mutect2, varscan2
- DUSP21 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.91); catalogued as COSV59133829; called by mutect2, varscan2
- DYNC2I1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV68104194; called by muse, mutect2, varscan2
- EEPD1 | c.1444A>T p.N482Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV54196947; called by mutect2, varscan2
- ELFN2 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101297475, COSV68744229; called by muse, varscan2
- ENAM | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as COSV68535600; called by muse, mutect2
- ENPP7 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.516); catalogued as rs868939491, COSV60385219; called by muse, mutect2, varscan2
- EPB41L2 | c.1968G>A p.M656I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100440397, COSV61353582; called by mutect2, varscan2
- EPHA1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as rs200836382, COSV51970054; called by mutect2, varscan2
- EXOSC10 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV58664653; called by mutect2, varscan2
- FAM13C | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53245942; called by muse, varscan2
- FAM221A | c.788A>C p.E263A | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV61387600; called by muse, varscan2
- FAM47A | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV60495360; called by muse, mutect2, varscan2
- FAT3 | c.11282C>T p.S3761F | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53093537; called by muse, mutect2
- FBXO3 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV55765692; called by mutect2, varscan2
- FGB | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV100122336; called by muse, mutect2, varscan2
- FLG | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as COSV64236266, COSV64239453; called by muse, mutect2
- FNDC1 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV51931415; called by muse, mutect2, varscan2
- FRMPD2 | c.1492T>C p.Y498H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59716661; called by muse, mutect2
- FRMPD4 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66216862; called by muse, mutect2
- FRMPD4 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.937); catalogued as COSV66221502; called by muse, mutect2
- GABRA4 | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as rs1378116476, COSV51925188; called by muse, mutect2, varscan2
- GBA3 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as COSV72437971; called by muse, mutect2, varscan2
- GFPT1 | c.1390A>G p.I464V (on ENST00000357308 / NM_001244710.2; = p.I446V on NM_002056.4) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV61947277; called by muse, mutect2
- GFRA1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV62604120; called by mutect2, varscan2
- GK | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV66736177; called by muse, mutect2
- GLI3 | c.3885C>G p.F1295L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV67885122, COSV67886944; called by muse, mutect2, varscan2
- GLIPR1 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56990324; called by mutect2, varscan2
- GMIP | c.1889T>G p.L630R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52555234; called by muse, mutect2
- GPC5 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65588549; called by muse, varscan2
- GPR139 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100429949, COSV58501556; called by mutect2, varscan2
- GRIK2 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs1271066576, COSV59710025; called by mutect2, varscan2
- GRIN2B | c.4094A>G p.N1365S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.055); catalogued as COSV74205399; called by muse, mutect2, varscan2
- GRM8 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.764); catalogued as rs1021001584, COSV58815708; called by muse, mutect2, varscan2
- HARS2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV99217989; called by muse, mutect2
- HIF1AN | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.588); catalogued as COSV54499921; called by muse, mutect2, varscan2
- HIVEP3 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56012724; called by muse, mutect2, varscan2
- HK2 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.988); catalogued as COSV51874211; called by muse, mutect2, varscan2
- HM13 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs17855400, COSV59438102; called by muse, mutect2, varscan2
- HOXA5 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV56072681; called by muse, mutect2
- HP | c.1106G>A p.W369* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV63325790; called by muse, mutect2, varscan2
- HTATSF1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV54478057; called by mutect2, varscan2
- HTR2A | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV66326961; called by mutect2, varscan2
- IDO1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs370075063, COSV99503510; called by mutect2, varscan2
- IFNA6 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762204032, COSV101207015; called by mutect2, varscan2
- IFNA7 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.228); catalogued as COSV53330828; called by muse, varscan2
- IFNE | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.14); catalogued as COSV100438736; called by muse, mutect2
- INSR | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57160261, COSV57166167; called by muse, mutect2
- IQUB | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV61238325; called by mutect2, varscan2
- ITGA4 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99275806; called by muse, varscan2
- ITGA8 | c.2947G>A p.D983N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV65226917; called by muse, varscan2
- KCNB1 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV65567087; called by muse, mutect2
- KDM5C | c.3652C>T p.R1218C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1288544172, COSV64763915; called by mutect2, varscan2
- KIF2B | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52128875; called by muse, mutect2
- KIF5A | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs199608047, COSV54052333; called by mutect2, varscan2
- KIFC1 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65728820; called by muse, mutect2, varscan2
- KIR2DL1 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52408390, COSV99383525; called by muse, mutect2, varscan2
- KLHL13 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.872); catalogued as COSV53244967; called by mutect2, varscan2
- KLHL13 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV53246133; called by mutect2, varscan2
- KRT15 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV54178060, COSV54179083; called by muse, mutect2, varscan2
- LBP | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54139502; called by muse, mutect2, varscan2
- LCOR | c.3822T>G p.S1274R | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.16); catalogued as COSV53715149; called by muse, varscan2
- LEPR | c.1962G>A p.M654I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV60750765; called by mutect2, varscan2
- LHFPL1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1396600137, COSV64333188; called by muse, mutect2, varscan2
- LIFR | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs746053471, COSV54686247; called by mutect2, varscan2
- LIPA | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as COSV51078440; called by muse, mutect2, varscan2
- LRCH4 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV59642792; called by muse, mutect2, varscan2
- LRFN1 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs934324238; called by mutect2, varscan2
- LRRTM3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV63663526; called by muse, mutect2, varscan2
- LRTM1 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55522883, COSV99836300; called by muse, mutect2
- MAGEC1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as rs1227207923, COSV53570377; called by muse, varscan2
- MAGEC1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV53569052; called by muse, mutect2
- MAGEC1 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.608); catalogued as rs1182977776, COSV53570404; called by muse, mutect2
- MAGEC1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1368273505, COSV53568938; called by muse, varscan2
- MAN2A2 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs199747893, COSV64637650; called by muse, mutect2
- MAP1A | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55807471; called by muse, mutect2, varscan2
- MED1 | c.2486A>G p.N829S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV56123538; called by muse, varscan2
- METTL2B | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52308366; called by muse, mutect2, varscan2
- MINDY4 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs755852563, COSV54672759; called by mutect2, varscan2
- MKX | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.143); catalogued as COSV65391850; called by mutect2, varscan2
- MLF2 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52570917; called by muse, mutect2, varscan2
- MMP1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100187803; called by mutect2, varscan2
- MMP13 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52823476; called by muse, varscan2
- MMP3 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV55405564; called by muse, mutect2, varscan2
- MMRN2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV62318073; called by muse, mutect2, varscan2
- MOCS1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100418326; called by mutect2, varscan2
- MOV10L1 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV99432860; called by mutect2, varscan2
- MROH2B | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV68182642; called by muse, mutect2, varscan2
- MS4A3 | c.281G>A p.W94* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV53935569; called by mutect2, varscan2
- MST1R | c.2588C>T p.P863L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376039698, COSV56566676; called by muse, mutect2, varscan2
- MTM1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV60334308; called by mutect2, varscan2
- MUC16 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV67456059; called by muse, mutect2, varscan2
- MUC17 | c.11258C>T p.T3753I | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60284222; called by muse, varscan2
- MYH13 | c.5293G>A p.D1765N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52823942; called by muse, varscan2
- MYO5C | c.2701C>T p.Q901* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99954191; called by mutect2, varscan2
- MYO9A | c.4367C>T p.T1456I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.36); catalogued as COSV61849222; called by muse, mutect2, varscan2
- NAP1L2 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV65172314; called by muse, mutect2, varscan2
- NCAN | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53048834; called by muse, mutect2, varscan2
- NCF2 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV62315083; called by muse, varscan2
- NEK2 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV65355595; called by muse, mutect2, varscan2
- NEXMIF | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as rs764458525; called by mutect2, varscan2
- NLGN4X | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52011478; called by muse, mutect2, varscan2
- NMS | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as rs770229478, COSV65258489; called by mutect2, varscan2
- NOMO1 | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1357773385, COSV55057659, COSV99814442; called by mutect2, varscan2
- NPSR1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV100705955, COSV62198748; called by muse, mutect2, varscan2
- OR3A2 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV68695236; called by mutect2, varscan2
- OR51S1 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs769830257, COSV59057920; called by mutect2, varscan2
- OR5K3 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV67349856; called by mutect2, varscan2
- OR6C75 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV58551741; called by muse, mutect2
- OR6N2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1399468421, COSV59410874; called by muse, mutect2, varscan2
- OTUD7A | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146170863, COSV61037326; called by mutect2, varscan2
- OVCH1 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.16); catalogued as COSV55478552; called by muse, mutect2
- PADI3 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV64934307; called by muse, mutect2, varscan2
- PANK1 | c.1180C>T p.P394S (on ENST00000307534 / NM_148977.2; = p.P169S on NM_138316.4) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.235); catalogued as COSV56807322; called by muse, mutect2, varscan2
- PAPPA | c.2887A>T p.M963L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV60280364; called by muse, mutect2, varscan2
- PAPPA2 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867975623, COSV100867625; called by mutect2, varscan2
- PBRM1 | c.1583A>G p.N528S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as rs201580633, COSV56268961, COSV56271832; called by muse, mutect2, varscan2
- PCDH10 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV52090724; called by mutect2, varscan2
- PCDH15 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as rs762029000, COSV57273789; called by mutect2, varscan2
- PCDHA2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.155); catalogued as COSV65366010; called by muse, mutect2, varscan2
- PCDHA4 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV63540173; called by muse, mutect2
- PCDHA6 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554132224, COSV65343232, COSV65346688; called by mutect2, varscan2
- PCDHB14 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53387647; called by mutect2, varscan2
- PCDHB2 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.175); catalogued as rs1554271675, COSV50567413; called by muse, mutect2
- PCDHB5 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); catalogued as rs267600417, COSV50648957; called by mutect2, varscan2
- PCED1B | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV71395053; called by muse, mutect2, varscan2
- PCNP | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as COSV54575644; called by muse, mutect2, varscan2
- PCSK5 | c.5485G>A p.D1829N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70448555; called by muse, mutect2, varscan2
- PDCD1 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV57691294; called by muse, mutect2, varscan2
- PHF8 | c.1625G>A p.R542Q (on ENST00000357988 / NM_001184896.1; = p.R506Q on NM_015107.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs183611806, COSV100154701, COSV57679411; called by mutect2, varscan2
- PHLDB2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.125); catalogued as rs1468508994, COSV67309707; called by muse, mutect2
- PI4KA | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs1242346793, COSV99744610; called by muse, mutect2, varscan2
- PKD1L1 | c.5274G>A p.M1758I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV56961556; called by muse, mutect2, varscan2
- PLA2G4A | c.1119dup p.M374Yfs*6 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | catalogued as rs750546323; called by mutect2, pindel, varscan2
- PLB1 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs369559866; called by mutect2, varscan2
- PLCB4 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV53797496; called by muse, varscan2
- PLP2 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV66239512; called by mutect2, varscan2
- PLPP4 | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV64827377; called by muse, mutect2, varscan2
- PNMA3 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64722093; called by muse, mutect2, varscan2
- POM121L12 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs766537069, COSV68692604; called by muse, mutect2, varscan2
- POTEA | c.1117G>A p.V373I (on ENST00000519951 / NM_001005365.2; = p.V327I on NM_001002920.1) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs370923298; called by mutect2, varscan2
- PPM1E | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV57572395; called by muse, mutect2
- PPP2R5C | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV58269627; called by muse, mutect2, varscan2
- PPP6C | c.348T>A p.S116R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65207475; called by muse, varscan2
- PRCP | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461709441, COSV57288163; called by muse, mutect2, varscan2
- PRDM12 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV53390231; called by mutect2, varscan2
- PRF1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.237); catalogued as rs776708052, CM1510976, COSV64614598; ClinVar: uncertain significance; called by mutect2, varscan2
- PRKCA | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.931); catalogued as COSV66101469; called by muse, mutect2, varscan2
- PRKX | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53323074; called by muse, mutect2, varscan2
- PTPN11 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61007477; called by mutect2, varscan2
- PTPRK | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868427142, COSV63894383; called by mutect2, varscan2
- PTPRN | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV99833723; called by muse, varscan2
- RAG1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55024532, COSV55026861; called by muse, mutect2
- RBBP7 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58112688; called by mutect2, varscan2
- REM1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52427621; called by muse, mutect2, varscan2
- RHOBTB1 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV61958150; called by mutect2, varscan2
- RP1L1 | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66753452; called by muse, mutect2, varscan2
- RPAP3 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1430653316, COSV50041523; called by muse, mutect2, varscan2
- RTN2 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.027); catalogued as COSV55593311; called by mutect2, varscan2
- RYR3 | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66783188; called by muse, mutect2
- SCN8A | c.4730G>A p.R1577K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61978828; called by muse, mutect2, varscan2
- SDK1 | c.3463G>A p.G1155R | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67362420; called by muse, mutect2, varscan2
- SEL1L3 | c.2231A>C p.K744T | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV53538390; called by muse, mutect2
- SELE | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60974643, COSV60977952; called by mutect2, varscan2
- SEMA3E | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57081352; called by muse, mutect2, varscan2
- SEMG2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.973); catalogued as COSV65647323; called by mutect2, varscan2
- SGCZ | c.554A>C p.E185A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101166875; called by muse, mutect2
- SHLD2 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.656); catalogued as COSV53953831; called by muse, mutect2, varscan2
- SI | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100017517, COSV52271939; called by mutect2, varscan2
- SLC12A3 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as rs764452069, COSV99343868; called by muse, varscan2
- SLC22A16 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.191); catalogued as COSV57928618; called by muse, mutect2, varscan2
- SLC2A12 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV51599125; called by mutect2, varscan2
- SLC4A4 | c.668C>T p.S223F (on ENST00000264485 / NM_001098484.3; = p.S179F on NM_003759.4) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52620274; called by mutect2, varscan2
- SLC8A3 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.203); catalogued as COSV63522383; called by muse, mutect2
- SLCO3A1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59227564; called by muse, mutect2, varscan2
- SMO | c.1903C>T p.Q635* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV50824146, COSV99976323; called by mutect2, varscan2
- SNRNP200 | c.3958C>T p.L1320F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV60488525; called by muse, mutect2, varscan2
- SORBS2 | c.803G>A p.G268D (on ENST00000284776 / NM_021069.5; = p.G361D on NM_003603.6) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV99509716; called by muse, mutect2, varscan2
- SPDYA | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61855734; called by muse, mutect2, varscan2
- SPPL2C | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV61292114; called by muse, mutect2, varscan2
- SPTA1 | c.5842G>A p.E1948K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100934085, COSV63751122; called by mutect2, varscan2
- SPTAN1 | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); catalogued as COSV63986151; called by mutect2, varscan2
- ST18 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs867886034, COSV52488269; called by mutect2, varscan2
- ST8SIA3 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen probably damaging (0.999); catalogued as COSV60655645; called by mutect2, varscan2
- STAU1 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61459654; called by muse, mutect2, varscan2
- STK38L | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.589); catalogued as COSV66521018; called by mutect2, varscan2
- STON1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs750444596, COSV59128535; called by mutect2, varscan2
- SUGCT | c.146T>G p.L49R | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59323076; called by muse, mutect2
- SYNE1 | c.5962G>A p.E1988K (on ENST00000367255 / NM_182961.4; = p.E1995K on NM_033071.3) | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV54944314; called by muse, mutect2
- TAS2R38 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV71885235; called by mutect2, varscan2
- TBC1D8B | c.3196C>T p.P1066S | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52177377; called by muse, mutect2, varscan2
- TCEAL2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV61197275; called by muse, mutect2
- TDRD3 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs750703449; called by mutect2, varscan2
- TECTA | c.3727C>T p.R1243C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs140869937; called by mutect2, varscan2
- TENM1 | c.3011G>A p.G1004E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100950390, COSV64428640; called by mutect2, varscan2
- TIE1 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.557); catalogued as COSV65249079; called by mutect2, varscan2
- TKTL2 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV54918125; called by muse, mutect2
- TLL2 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773055615, COSV63570530; called by mutect2, varscan2
- TMC5 | c.1496G>A p.R499K (on ENST00000396229 / NM_001105248.1; = p.R253K on NM_024780.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV54902624; called by muse, mutect2
- TMEM217 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs267601006, COSV60825401; called by muse, mutect2, varscan2
- TMPRSS2 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59821713; called by mutect2, varscan2
- TMTC3 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57123247, COSV99897921; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2816C>T p.T939I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64100530; called by muse, mutect2, varscan2
- TRAM1L1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.787); catalogued as COSV60291387; called by muse, mutect2
- TRBV5-1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs758107657; called by mutect2, varscan2
- TRIM48 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1177801575, COSV70161223; called by muse, mutect2
- TRIML2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.401); catalogued as COSV58715357; called by mutect2, varscan2
- TRPC4AP | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52678324; called by mutect2, varscan2
- TSPYL5 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV59071293; called by muse, mutect2, varscan2
- TTN | c.97627G>A p.E32543K (on ENST00000591111; = p.E25119K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | PolyPhen probably damaging (0.994); catalogued as rs776306284, COSV59965488; called by mutect2, varscan2
- TTN | c.97015G>A p.E32339K (on ENST00000591111; = p.E24915K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | PolyPhen probably damaging (0.997); catalogued as COSV59965521; called by muse, mutect2, varscan2
- TTN | c.83390C>T p.P27797L (on ENST00000591111; = p.P20373L on NM_003319.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV59965550; called by muse, varscan2
- TTN | c.70085C>T p.A23362V (on ENST00000591111; = p.A15938V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | PolyPhen possibly damaging (0.772); catalogued as COSV59965577; called by muse, mutect2, varscan2
- TTN | c.38404G>A p.G12802R (on ENST00000591111; = p.G5378R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | PolyPhen probably damaging (1); catalogued as rs1470566986; called by muse, mutect2
- TTN | c.5488G>A p.G1830S (on ENST00000591111; = p.G1784S on NM_003319.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | PolyPhen benign (0.072); catalogued as rs1447527169, COSV59966011, COSV60172067; called by muse, mutect2, varscan2
- TUBA1B | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.045); catalogued as COSV60136612; called by muse, mutect2
- TUBA3E | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); catalogued as rs369136801; called by mutect2, varscan2
- TUT7 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as COSV104373438, COSV52894809; called by muse, mutect2, varscan2
- UPF2 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs866288655, COSV62659584; called by muse, mutect2, varscan2
- USP7 | c.2935C>T p.Q979* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as COSV61213770; called by muse, mutect2
- VPS13C | c.4783G>A p.D1595N (on ENST00000644861 / NM_020821.3; = p.D1552N on NM_017684.5) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV51140722; called by muse, mutect2, varscan2
- VPS35 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV54477782; called by mutect2, varscan2
- VSTM4 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1027555232, COSV53677328; called by muse, mutect2, varscan2
- WNT7A | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781226883; called by mutect2, varscan2
- WNT7B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV59749057; called by mutect2, varscan2
- XDH | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65147824; called by mutect2, varscan2
- ZFHX3 | c.6716G>A p.W2239* | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | catalogued as COSV51713670; called by muse, mutect2, varscan2
- ZHX1 | c.2354T>C p.L785P | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV52876016; called by muse, mutect2, varscan2
- ZIM3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.645); catalogued as COSV54141327; called by mutect2, varscan2
- ZMIZ1 | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as COSV57892722; called by muse, mutect2
- ZNF239 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs1430204905, COSV60018395; called by muse, mutect2, varscan2
- ZNF334 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs1175045036, COSV61618283; called by muse, mutect2, varscan2
- ZNF536 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62821617; called by muse, mutect2
- ZNF536 | c.2990G>A p.S997N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62821624, COSV62828637; called by muse, mutect2, varscan2
- ZNF608 | c.2329C>T p.Q777* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV60436697; called by mutect2, varscan2
- ZP4 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63911567; called by muse, mutect2, varscan2
- AREG | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by mutect2, varscan2
- GRAMD2B | c.359_360insT p.T121Nfs*104 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- IGKV1D-13 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NBPF11 | c.989-1G>A p.X330_splice | Splice Site (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- OR8G2P | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PRAMEF20 | c.503T>G p.F168C | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- TRAV26-1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ABCD2 | c.1548G>A p.G516= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs1178000286, COSV58050901; called by muse, mutect2, varscan2
- ACRBP | c.996C>T p.I332= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs773338294, COSV57522916, COSV57523451; called by mutect2, varscan2
- ACSM2A | c.1531C>T p.L511= (on ENST00000219054; = p.L432= on NM_001308169.2) | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV54583578; called by muse, varscan2
- ACTL6B | c.1050G>A p.G350= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs267601183, COSV50514201; called by mutect2, varscan2
- ADAM28 | c.1746C>T p.F582= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV56097329; called by muse, mutect2
- ADCY8 | c.915C>T p.I305= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV53902411; called by mutect2, varscan2
- AKAP9 | c.2343A>G p.K781= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs879510313, COSV62342421; called by muse, mutect2
- AMPD2 | c.1338C>T p.S446= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs772949801, COSV56647568; called by mutect2, varscan2
- ANK3 | c.11091C>T p.S3697= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55050620; called by muse, mutect2, varscan2
- ANKRD7 | c.126G>A p.K42= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV54554304; called by muse, mutect2, varscan2
- APOB | c.10692G>A p.E3564= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as COSV51929933; called by muse, mutect2
- ASB15 | c.609C>T p.V203= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1423945812, COSV51924845; called by muse, mutect2, varscan2
- ATP8B4 | c.1854G>A p.A618= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1401930109, COSV52709667; called by mutect2, varscan2
- AUTS2 | c.2136C>T p.F712= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV61392040, COSV61420254; called by muse, varscan2
- AVPR1B | c.519C>T p.S173= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV65637896; called by muse, mutect2, varscan2
- B3GALT5 | c.324G>A p.E108= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV58199869; called by mutect2, varscan2
- BCL11B | c.195C>T p.F65= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV61734713; called by mutect2, varscan2
- BCL9 | c.2721C>T p.S907= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV52342543; called by muse, mutect2, varscan2
- BLM | c.3378C>T p.I1126= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as COSV61922956, COSV61923761; called by muse, mutect2
- BMS1 | c.936C>T p.F312= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs755403632, COSV65733461; called by mutect2, varscan2
- BRAT1 | c.2172C>T p.L724= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV61394814, COSV61397239; called by muse, mutect2, varscan2
- C18orf54 | c.663C>T p.S221= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55617681; called by mutect2, varscan2
- C1QTNF2 | c.489G>A p.G163= (on ENST00000393975; = p.G118= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV67432379; called by muse, mutect2, varscan2
- C2 | c.2052C>T p.F684= | Silent (SNP) | VAF 20/245 reads (8%) | catalogued as COSV100190712; called by muse, mutect2
- C2orf16 | c.2715G>A p.R905= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV62674652; called by muse, mutect2, varscan2
- CALU | c.538C>T p.L180= | Silent (SNP) | VAF 12/151 reads (8%) | catalogued as COSV50821434; called by muse, mutect2
- CARD11 | c.2073C>T p.F691= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1301445086, COSV62754714; called by mutect2, varscan2
- CASP4 | c.40T>C p.L14= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs929648640, COSV67744297; called by muse, mutect2, varscan2
- CD3E | c.468G>A p.K156= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV62345519; called by muse, varscan2
- CDCP2 | c.279G>A p.G93= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV61283201, COSV61283226; called by muse, mutect2, varscan2
- CEACAM4 | c.60C>T p.I20= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV55730949, COSV99032678; called by mutect2, varscan2
- CES4A | c.150C>T p.V50= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV58652553; called by muse, varscan2
- CFAP46 | c.6078G>A p.E2026= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV54150711; called by muse, mutect2
- CHRNB4 | c.831C>T p.F277= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1312148943, COSV55715447; called by mutect2, varscan2
- CLEC4F | c.1530G>A p.K510= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV55478827; called by muse, mutect2, varscan2
- CNTNAP4 | c.1821C>T p.Y607= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV56673104; called by muse, mutect2
- CTPS2 | c.117C>T p.I39= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs772522874, COSV63721818; called by mutect2, varscan2
- CYP4A11 | c.210G>A p.Q70= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs758693249, COSV60222912; called by mutect2, varscan2
- DCAF12L2 | c.1281C>T p.F427= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV63580877; called by muse, mutect2, varscan2
- DGKK | c.2241C>T p.P747= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV65706948; called by muse, mutect2
- DISP3 | c.2481C>T p.F827= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV53824346; called by muse, mutect2, varscan2
- DMBT1 | c.708G>A p.L236= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as COSV57539179; called by muse, mutect2
- DNAH11 | c.5841C>T p.F1947= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1277019482, COSV60948732, COSV60975213; called by mutect2, varscan2
- DPPA2 | c.39C>T p.F13= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV72117992, COSV72118061; called by muse, mutect2, varscan2
- DUOX1 | c.1281C>T p.G427= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs745611601, COSV58479046; called by mutect2, varscan2
- ELAVL2 | c.474C>T p.V158= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs781736838, COSV56359793; called by mutect2, varscan2
- ELF4 | c.1092G>A p.L364= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV57452021; called by muse, varscan2
- ELMO3 | c.1437G>A p.Q479= (on ENST00000652269; = p.Q426= on NM_024712.5) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100440682; called by muse, mutect2
- EPHA6 | c.882C>T p.V294= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV67560373; called by muse, varscan2
- EPHA6 | c.2244G>A p.G748= (on ENST00000389672 / NM_001080448.3; = p.G140= on NM_173655.4) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV67562555; called by mutect2, varscan2
- ERC2 | c.1032G>A p.V344= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs1031350431, COSV55611741; called by mutect2, varscan2
- FAM47A | c.510G>A p.E170= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV60495381; called by muse, mutect2
- FBH1 | c.180C>T p.I60= (on ENST00000362091 / NM_178150.3; = p.I111= on NM_032807.4) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV62982122; called by mutect2, varscan2
- FERMT1 | c.1494G>A p.R498= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV54091962; called by mutect2, varscan2
- FGF10 | c.561G>A p.R187= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV52932273; called by muse, mutect2, varscan2
- GABRA3 | c.519G>A p.L173= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV64797087; called by muse, varscan2
- GARNL3 | c.366C>T p.F122= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV59225026; called by muse, mutect2, varscan2
- GCN1 | c.5217C>T p.I1739= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs752430496, COSV56105740, COSV56111131; called by mutect2, varscan2
- GCNT3 | c.228G>A p.G76= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs1378354359, COSV68532060; called by muse, mutect2, varscan2
- GIMAP1 | c.894G>A p.E298= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1374692819, COSV56187645; called by muse, mutect2, varscan2
- GIMAP6 | c.141G>A p.G47= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs138777121, COSV61032937; called by muse, mutect2
- GLE1 | c.439C>T p.L147= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs537504118, COSV59407137; called by muse, mutect2
- GRM3 | c.1635C>T p.T545= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV64469455; called by mutect2, varscan2
- GRM3 | c.1956C>T p.F652= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs370138882; called by mutect2, varscan2
- GRM3 | c.2239C>T p.L747= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100862592, COSV64469462; called by muse, mutect2, varscan2
- HARS2 | c.873C>T p.S291= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV99217990; called by muse, mutect2
- HDHD3 | c.204C>T p.G68= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV53056846; called by mutect2, varscan2
- HTR1E | c.489C>T p.H163= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100541328, COSV59507405, COSV59508158; called by mutect2, varscan2
- IFIT1B | c.759C>T p.V253= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV65663314; called by muse, mutect2
- IGHG2 | c.739C>T p.L247= | Silent (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- KLC4 | c.657C>T p.I219= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV52434583; called by muse, mutect2, varscan2
- LRP4 | c.2076C>T p.P692= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV66134952; called by muse, mutect2
- LRRC23 | c.984G>A p.Q328= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV50387568; called by muse, mutect2
- MICAL3 | c.897C>T p.F299= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs751823263, COSV52891604; called by mutect2, varscan2
- MLF2 | c.471C>T p.I157= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV52570908; called by muse, mutect2, varscan2
- MOXD1 | c.1053C>T p.I351= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV60943009; called by mutect2, varscan2
- MRGPRX1 | c.240T>C p.L80= | Silent (SNP) | VAF 9/149 reads (6%) | catalogued as rs1293995223, COSV100246096, COSV57106467; called by muse, mutect2
- MTMR12 | c.970C>T p.L324= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV53783316; called by muse, mutect2
- NCKAP1L | c.2589G>A p.Q863= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV53205129; called by muse, mutect2, varscan2
- NEBL | c.2586G>A p.Q862= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV65802175; called by muse, mutect2, varscan2
- NEK8 | c.390G>A p.K130= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV52043866; called by muse, mutect2
- NIN | c.3304T>C p.L1102= | Silent (SNP) | VAF 8/133 reads (6%) | catalogued as COSV55385136; called by muse, mutect2
- NLRP4 | c.234G>A p.K78= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV56711305; called by muse, mutect2, varscan2
- NPAS4 | c.2050C>T p.L684= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV60649639; called by muse, mutect2, varscan2
- NPSR1 | c.468C>T p.F156= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV62196839; called by muse, mutect2, varscan2
- NR5A2 | c.24G>A p.G8= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV52647948; called by muse, varscan2
- OR2A2 | c.660C>T p.I220= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs777302846, COSV68871317; called by mutect2, varscan2
- OR2G2 | c.540C>T p.F180= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs996909804, COSV100189588, COSV60739959; called by mutect2, varscan2
- OR2M5 | c.340C>T p.L114= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV63545996; called by muse, varscan2
- OR2T11 | c.264C>T p.I88= | Silent (SNP) | VAF 5/29 reads (17%) | called by mutect2, varscan2
- OR3A2 | c.414C>T p.P138= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV68695024; called by muse, varscan2
- OR5B17 | c.837C>T p.I279= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1247924480, COSV62160103; called by mutect2, varscan2
- OR5B2 | c.606C>T p.S202= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs766471842, COSV56907891, COSV56908196; called by mutect2, varscan2
- OR5D13 | c.885G>A p.R295= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1295811448, COSV62332673; called by mutect2, varscan2
- OSR1 | c.306C>T p.I102= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99693554; called by mutect2, varscan2
- OTOGL | c.6687G>A p.L2229= (on ENST00000547103; = p.L2220= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs1396173510, COSV54015264; called by muse, varscan2
- PCDHGA1 | c.2247C>T p.F749= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV65295816; called by mutect2, varscan2
- PCLO | c.10236G>A p.K3412= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV61625276; called by mutect2, varscan2
- PCLO | c.9753C>T p.I3251= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV61625293, COSV61629451; called by mutect2, varscan2
- PCNX2 | c.915G>A p.Q305= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV50789967; called by muse, mutect2, varscan2
- PKD1L1 | c.3345C>T p.D1115= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV56961569; called by muse, mutect2, varscan2
- POLR3B | c.570C>T p.I190= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs772944396, COSV57277614; called by mutect2, varscan2
- POT1 | c.375C>T p.F125= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV62928375; called by mutect2, varscan2
- PROSER3 | c.732C>T p.I244= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56552961; called by muse, mutect2, varscan2
- PRPF4B | c.681C>T p.S227= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as COSV61783775; called by muse, mutect2
- PSEN1 | c.414C>T p.I138= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV56193758; called by mutect2, varscan2
- PTPRC | c.258C>T p.S86= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV61408845; called by muse, mutect2, varscan2
- RAB25 | c.351G>A p.T117= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1438147085, COSV63108486; called by mutect2, varscan2
- RNASET2 | c.390C>T p.S130= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV50351344; called by muse, mutect2, varscan2
- RNF122 | c.408C>T p.P136= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs1270039445, COSV56359053; called by muse, mutect2, varscan2
- RP1L1 | c.5517G>A p.E1839= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs1282427158, COSV66753446; called by muse, mutect2, varscan2
- RPL10 | c.279C>T p.P93= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs1033580330, COSV50010106; called by muse, mutect2, varscan2
- RPS2 | c.405C>T p.G135= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs761932050, COSV51909700; called by mutect2, varscan2
- RYR1 | c.7002C>T p.F2334= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1447367510, COSV62093502; called by muse, mutect2, varscan2
- SALL1 | c.2469C>T p.N823= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV51755467; called by muse, mutect2
- SCN2A | c.1422C>T p.F474= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51836851; called by mutect2, varscan2
- SDR42E1 | c.993G>A p.K331= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV61093946; called by muse, mutect2, varscan2
- SETDB2 | c.1836T>C p.D612= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV51643839; called by muse, mutect2
- SIGLEC12 | c.285C>T p.L95= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs773612576, COSV52460580; called by mutect2, varscan2
- SLAMF9 | c.777C>T p.V259= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs758816630, COSV63636430; called by mutect2, varscan2
- SLC16A12 | c.168C>T p.F56= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs990357973; called by muse, mutect2, varscan2
- SLC35F1 | c.364C>T p.L122= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1326550476, COSV64501337; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2127G>A p.R709= (on ENST00000540229 / NM_001371097.1; = p.R648= on NM_001009562.4) | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV67440296; called by mutect2, varscan2
- SLITRK3 | c.945C>T p.S315= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs778044687, COSV53846842; called by muse, mutect2, varscan2
- SMAD3 | c.1236C>T p.T412= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV59282258; called by muse, mutect2, varscan2
- SMO | c.1902C>T p.P634= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99976321; called by muse, mutect2
- SNAP47 | c.1008C>T p.I336= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1416710009, COSV59917422; called by muse, mutect2, varscan2
- SPATA17 | c.1065A>G p.S355= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as COSV65120767; called by muse, mutect2
- SPEN | c.2874T>C p.L958= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV65359874; called by muse, mutect2
- SPHKAP | c.2838G>A p.A946= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs763319527, COSV60872113; called by mutect2, varscan2
- SPIC | c.465G>A p.G155= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs745964388, COSV54690601; called by mutect2, varscan2
- STRC | c.4725C>T p.F1575= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs944428663, COSV100294450; called by mutect2, varscan2
- TAS1R2 | c.159C>T p.F53= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV64743422; called by muse, mutect2, varscan2
- TAS2R38 | c.117G>A p.V39= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV71885236; called by mutect2, varscan2
- TNXB | c.5637C>T p.I1879= (on ENST00000647633; = p.I1632= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV64476271; called by muse, mutect2, varscan2
- TRAPPC9 | c.2481C>T p.V827= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs747013383, COSV66896298; called by mutect2, varscan2
- TRAV13-1 | c.280C>T p.L94= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- TRIML1 | c.1104C>T p.L368= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV60193817, COSV60196653; called by mutect2, varscan2
- TSGA10IP | c.726G>A p.S242= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1280542210, COSV73245250; called by mutect2, varscan2
- TTN | c.7140C>T p.S2380= (on ENST00000591111; = p.S2334= on NM_003319.4) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV59965972; called by muse, mutect2, varscan2
- UNC93A | c.319C>T p.L107= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV57807718; called by muse, mutect2, varscan2
- ZCWPW1 | c.1213C>T p.L405= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV52199719; called by muse, mutect2
- ZNF558 | c.759C>T p.S253= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV56862696; called by muse, mutect2, varscan2
- ZNF683 | c.93C>T p.F31= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV62873862; called by mutect2, varscan2
- ACSL5 | c.-36T>C | 5'UTR (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100634492; called by muse, mutect2
- AP001042.1 | n.2441A>G | RNA (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- MORF4 | n.579C>T | RNA (SNP) | VAF 16/139 reads (12%) | called by mutect2, varscan2
- OR2W5 | n.566G>A | RNA (SNP) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- PLXNA4 | c.1371+4304G>A | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as rs1370209049, COSV100322748; called by muse, varscan2
- RMDN2 | c.453-22081C>T | Intron (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52222043; called by mutect2, varscan2
- RNU6-1178P | chr17:20895803 T>C | 5'Flank (SNP) | VAF 7/66 reads (11%) | catalogued as COSV60001431; called by muse, mutect2, varscan2
